CCDI case PBCBXZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/c24c243e-5a55-46b9-8208-3907d65de279

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 17.5 years (6,391 days).

Biospecimens (2 samples)
- Sample 0DPU2K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPU2W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
